Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6510, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6510-01A (Primary Tumor).

Examination: Histopathological examination

Material: Partial resection of organ – rectum and sigmoid colon

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis:

TCGA – E1 – 6510

Examination performed on:

Macroscopic description:

A 12.4 cm length of large intestine with mesorectum tissue of 2.5 cm in thickness. A cauliflower-shaped tumour sized 5.2 x 5.3 x 1.2 cm found in the mucosa. The lesion surrounding 80% of the intestine circumference, placed 4.4 cm from one of the incision lines and 2.9 cm from the opposite one.

Microscopic description:

Adenocarcinoma tubulopapillare (G2).

Infiltratio carcinomatosa profunda tunicae muscularis propriae recti.

Incision lines free of neoplastic lesions.

Adenoma tubulopapillare cum dysplasia gradu mediocri (LG) found in the proximity of one of the intestine ends.

Lymphonodulitis reactiva No III.

Histopathological diagnosis:

Adenocarcinoma tubulopapillare recti. Tubulopapillar adenocarcinoma of the rectum.

(G2, Dukes A, Astler-Coller BI, pT2, pNO).

Examination performed on:

SUPPLEMENTARY TEST

Signs of fatty tissue penetration found in specimen A in supplementary test. Full diagnosis:

Adenocarcinoma tubulopapillare recti. Tubulopapillar adenocarcinoma of the rectum. (G2, Dukes B, Astler-Coller B2, pT3, pNO).

Source: NCI Genomic Data Commons file 3a419183-e445-4ba4-aff9-90eaf57a5dea (TCGA-EI-6510.E0E62F18-30C3-48C6-82D1-8EBC3C7DCEA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).